Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9J1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9J1-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M Service: Received:
Reported:
Submitting Physician:
Pathologist:
Intraop Pathologist:
Performing Physician:

CLINICAL HISTORY:

7-YEAR-OLD MALE WITH RENAL MASS 3.3 CM, SMOKED
STOPPED IN
(STENTS X 2 IN).

HYPERTENSION.

PREOPERATIVE DIAGNOSIS:

LEFT RENAL MASS.

SPECIMEN TYPE(S):

- A: TIP OF 11TH RIB, GROSS ONLY
- B: LEFT PERINEPHRIC FAT FS
- C: LEFT RENAL MASS FS
- D: ABDOMINAL WALL LESION

*ICD-6.3
Carcinoma, papillary renal cell 8264/3
Site @ Kidney N65 C64.9
JMS 4/28/14*

FINAL DIAGNOSIS:

- A. "TIP OF 11TH RIB," EXCISION:
Portion of unremarkable rib (Gross Diagnosis Only).
Portions of muscle and adipose tissue with no significant pathological change.
- B. "LEFT PERINEPHRIC FAT," EXCISION:
Fibroadipose tissue, negative for carcinoma.
- C. "LEFT RENAL MASS," PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type, Fuhrman nuclear grade 2-3 of 4.
See Key Pathological Findings.

KEY PATHOLOGICAL FINDINGS

Tumor type:	Renal cell carcinoma, papillary type.
Nuclear grade:	Fuhrman nuclear grade 2-3 of 4.
Pattern of growth:	Solid.
Tumor size:	3.0 cm.
Extend through Renal Capsule:	Not identified.
Invasion of Gerota's Fascia:	Not applicable.
Renal vein invasion:	Not applicable.
Surgical margins:	Free; however, carcinoma present less than 1mm from parenchymal resection margin.
Non-neoplastic kidney:	Mild chronic inflammation.
Adrenal gland:	Not applicable.
Lymph nodes:	Not applicable.
Pathologic stages:	pT1aNXMX. Yes.

- D. "ABDOMINAL WALL LESION," EXCISION:
Benign verrucoid keratosis (See Comment).

COMMENT: The differential diagnoses include verrucoid seborrheic keratosis, regressing verruca, and in an appropriate clinical background a variant of condyloma acuminatum without apparent associated HPV features. concurs with the diagnosis (slide D1).

I, the attending pathologist, personally reviewed the entire pathology

[page 2 of 2]
case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:

NA

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

FSB1. LEFT PERINEPHRIC FAT:
Consistent with fat, no evidence of malignancy.

FSCL. LEFT RENAL MASS:
Malignant renal neoplasm. The tumor is less than 1 mm from the inked resection margin.

COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by

I, _____, MD have performed the intraoperative consultation and issued the above diagnoses.

GROSS DESCRIPTION:

A. Specimen A is received fresh labeled "tip of 11th rib gross only." The specimen consists of 3.3-cm in length portion of rib with grossly unremarkable resection margin and with 3.0 x 2.0 x 1.5-cm attached fragment of tan/red brown muscle. No tissue is submitted to the tissue procurement laboratory. Representative section of the muscle submitted in 1 cassette, A.

B. Specimen B is received fresh labeled "left perinephric fat, rule out cancer, inked margin." The specimen consists of 1.5 x 1.5 x 0.6-cm irregular fragment of tan pale-yellow, soft, lobulated adipose tissue. The specimen is oriented according to the surgeon's designation and resection margin inked black. The specimen is serially sectioned to reveal grossly unremarkable cut surface. Representative section of the specimen submitted for frozen section analysis and frozen section remnant submitted in 1 cassette, FSB.

C. Specimen C is received fresh labeled "left renal mass." The specimen consists of 3.5 x 1.2 x 2.2-cm partial nephrectomy specimen. Prior to sectioning, the specimen is inked as follows:

Parenchymal resection margin: Black.
Capsular surface: Green.

On sectioning, the specimen reveals an irregular-to-ovoid, soft, focally hemorrhagic and necrotic tumor measuring 3.0 x 2.8 x 2.0 cm. The tumor is bulging, but does not appear to extend through the renal capsule. The tumor is less than 0.1 cm from the closest parenchymal resection margin, which is inked black. Representative sections of the specimen with tumor in relation to closest parenchymal resection margin submitted for frozen section analysis and frozen section remnant submitted in 1 cassette, FSCL. Representative sections submitted to the tissue procurement laboratory. Additional sections of the tumor submitted in 4 cassettes, CL-C4.

D. Specimen D is received fresh labeled "abdominal wall lesion." The specimen consists of an irregular-to-oval unoriented fragment of tan-gray skin consistent with exophytic lesion measuring 1.3 x 1.0 x 0.4 cm. The resection margin of the lesion is inked black. The specimen is serially sectioned and submitted entirely in 1 cassette, D.

Source: NCI Genomic Data Commons file b6a319aa-68cc-49ec-9a61-1cdc3a5e1347 (TCGA-2Z-A9J1.9B82DA05-EB5D-44EB-BE97-BD002DD30955.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).